Somatic mutation profile of tumor specimen TCGA-NH-A5IV-01A (aliquot TCGA-NH-A5IV-01A-42D-A36X-10) from TCGA case TCGA-NH-A5IV, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-NH-A5IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4d85a05-a8fb-445e-a7ac-087883924a45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A5IV-10A (Blood Derived Normal), aliquot TCGA-NH-A5IV-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce1d46b8-5bea-4da1-9b0c-f4d215eb7b52

The open-access MAF lists 2,902 somatic variants for this specimen: 2,211 protein-altering or splice-affecting, 640 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,495, Silent 640, Frame Shift Del 498, Frame Shift Ins 77, Nonsense Mutation 64, Splice Site 34, In Frame Del 25, Splice Region 16, Intron 16, RNA 13, 3'Flank 7, 5'UTR 5.

Variants (750 of 2,902; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.1171del p.R391Vfs*12 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | catalogued as rs751404811, CM045926, CM138787; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 54/119 reads (45%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 50/110 reads (45%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ARSA | c.418del p.H140Ifs*8 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs745884435, CD085806, CM085251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 44/75 reads (59%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 64/195 reads (33%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- CAV3 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs116840795, CM040985, COSV57480720; ClinVar: likely pathogenic / not provided / uncertain significance; called by muse, mutect2, varscan2
- CHST3 | c.533del p.G178Afs*38 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs769540174; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IREB2 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as rs779567692, COSV51921552; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNA1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28933383, CM076245, CM962692, CM993940, COSV66836391; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 21/58 reads (36%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 58/156 reads (37%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.741dup p.R248Tfs*8 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | catalogued as rs267608041; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- NPHS1 | c.2515del p.Q839Rfs*8 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs386833918, CD097350, COSV100799747; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 69/171 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PROK2 | c.297del p.F99Lfs*28 (on ENST00000295619 / NM_001126128.2; = p.F78Lfs*28 on NM_021935.4) | Frame Shift Del (DEL) | VAF 29/104 reads (28%) | catalogued as rs768413190; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- RYR1 | c.14129+1G>A p.X4710_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as rs142929172, COSV62110710; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 48/112 reads (43%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TCF12 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880016, CM1411541, COSV51003557, COSV99032766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.821del p.N274Tfs*10 | Frame Shift Del (DEL) | VAF 31/70 reads (44%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TNNI3 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs104894729, CM030288, COSV52571799; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- XRCC2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 35/65 reads (54%) | catalogued as rs750903875, CM122769, COSV63770268; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100228373; called by muse, mutect2, varscan2
- AADACL4 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs150325490; called by muse, mutect2, varscan2
- AATK | c.3536G>A p.S1179N (on ENST00000326724 / NM_001080395.3; = p.S1076N on NM_004920.2) | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.018); catalogued as rs760998878, COSV100352426; called by muse, mutect2, varscan2
- AATK | c.664T>C p.S222P (on ENST00000326724 / NM_001080395.3; = p.S119P on NM_004920.2) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV100452605; called by muse, mutect2, varscan2
- ABCA2 | c.5263C>T p.R1755C (on ENST00000614293; = p.R1725C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1362222609, COSV55802414; called by muse, mutect2, varscan2
- ABCA7 | c.5683C>T p.R1895C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs778055293, COSV54028464; called by muse, mutect2, varscan2
- ABCB6 | c.301del p.A101Pfs*149 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs768732686; called by mutect2, varscan2
- ABCC10 | c.206G>A p.R69Q (on ENST00000372530 / NM_001198934.2; = p.R26Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750724181, COSV99766374, COSV99766572; called by muse, mutect2, varscan2
- ABCC11 | c.1729G>A p.V577I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs759098000, COSV100750434; called by muse, mutect2, varscan2
- ABCC2 | c.2020G>A p.G674S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778892744, COSV100966328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC3 | c.3884C>T p.S1295F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53316904, COSV99558514; called by muse, mutect2, varscan2
- ABHD12 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV100194115; called by muse, mutect2, varscan2
- AC097637.1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1162856520, COSV59726161; called by muse, mutect2, varscan2
- AC139530.2 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV100230107; called by muse, mutect2, varscan2
- ACACB | c.5831G>T p.R1944M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58134635; called by muse, varscan2
- ACAP1 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as rs781478005, COSV99341324; called by muse, mutect2, varscan2
- ACP6 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781901499, COSV65077762; called by muse, mutect2
- ACP7 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.805); catalogued as COSV100488376; called by mutect2, varscan2
- ACSF2 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV99365991; called by muse, mutect2, varscan2
- ACSL4 | c.1515C>T p.G505= (on ENST00000340800 / NM_022977.2; = p.G464= on NM_004458.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 126/315 reads (40%) | catalogued as rs779703364, COSV61614853; called by muse, mutect2, varscan2
- ACSL5 | c.508G>A p.A170T (on ENST00000354273; = p.A226T on NM_016234.3) | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100634386; called by muse, mutect2, varscan2
- ACSL5 | c.769G>A p.V257I (on ENST00000354273; = p.V313I on NM_016234.3) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs186230656, COSV100634387; called by muse, mutect2
- ACSM2B | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs148136861; called by muse, mutect2, varscan2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs745681981, COSV53623223; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 34/72 reads (47%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA2 | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1255303834, COSV99375647; called by muse, mutect2, varscan2
- ADAM15 | c.1955T>C p.L652P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99664590; called by muse, mutect2, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 80/221 reads (36%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAM29 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs148692882, COSV63663505; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS13 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100746897; called by muse, mutect2, varscan2
- ADAMTS16 | c.3028G>A p.A1010T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99939533; called by muse, mutect2, varscan2
- ADAMTS17 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558730527, COSV51484309; called by muse, mutect2, varscan2
- ADAMTS18 | c.1493C>A p.P498H | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99270793; called by muse, mutect2, varscan2
- ADAMTS20 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as COSV101238664; called by muse, mutect2, varscan2
- ADAMTS6 | c.2597T>C p.V866A | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.309); catalogued as COSV100068194; called by muse, mutect2, varscan2
- ADAMTS6 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1029158103, COSV66856752; called by muse, mutect2, varscan2
- ADAMTS7 | c.2590del p.L864Wfs*93 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs1309405734, COSV66307015; called by mutect2, varscan2
- ADAMTS7 | c.2141A>G p.D714G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV66307236; called by muse, mutect2, varscan2
- ADAMTS9 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs759029793, COSV99898396; called by muse, mutect2, varscan2
- ADAMTS9 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 86/175 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99898397; called by muse, varscan2
- ADAMTSL3 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV99716343; called by muse, mutect2, varscan2
- ADARB1 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100653552; called by muse, mutect2, varscan2
- ADARB2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs140367778; called by muse, mutect2, varscan2
- ADCY1 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99811035; called by muse, mutect2
- ADCY3 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as COSV53164396, COSV53168054; called by muse, mutect2, varscan2
- ADCY5 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV71901346; called by muse, mutect2, varscan2
- ADGRA1 | c.1345del p.R449Afs*88 | Frame Shift Del (DEL) | VAF 23/72 reads (32%) | catalogued as COSV66927805; called by mutect2, pindel, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- ADGRE5 | c.2011G>A p.A671T (on ENST00000242786 / NM_078481.4; = p.A578T on NM_001784.5) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1159175516, COSV99660066; called by muse, mutect2, varscan2
- ADGRG2 | c.2441G>T p.R814L (on ENST00000379869 / NM_001079858.3; = p.R811L on NM_005756.4) | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV61337768, COSV61340199; called by muse, mutect2, varscan2
- ADGRG4 | c.5348dup p.N1783Kfs*3 | Frame Shift Ins (INS) | VAF 134/358 reads (37%) | catalogued as rs760259488; called by mutect2, pindel, varscan2
- ADGRG6 | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as rs749312742, COSV51594514; called by muse, mutect2, varscan2
- ADGRL2 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54666618; called by muse, mutect2, varscan2
- ADGRL3 | c.1766G>A p.C589Y (on ENST00000506720 / NM_001322402.2; = p.C521Y on NM_015236.6) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV72230571; called by muse, mutect2, varscan2
- ADGRL3 | c.2194C>A p.R732S (on ENST00000506720 / NM_001322402.2; = p.R664S on NM_015236.6) | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV72230572; called by muse, mutect2, varscan2
- ADGRL4 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 142/380 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV100875481; called by muse, mutect2, varscan2
- ADGRV1 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV101315279; called by muse, mutect2
- ADGRV1 | c.15010G>A p.V5004I | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368077476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADH1A | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99265617; called by muse, mutect2
- ADNP | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV100823613; called by muse, mutect2, varscan2
- ADRA1A | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV99369727; called by muse, mutect2
- AFF2 | c.3664A>G p.I1222V | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53989403; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 63/203 reads (31%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as COSV58317085; called by mutect2, varscan2
- AGAP1 | c.1384A>G p.N462D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.038); catalogued as COSV58318349, COSV58327453; called by muse, mutect2, varscan2
- AGL | c.1594C>G p.P532A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99648188; called by muse, mutect2, varscan2
- AGL | c.3260-1G>T p.X1087_splice | Splice Site (SNP) | VAF 96/272 reads (35%) | catalogued as COSV99648191; called by muse, varscan2
- AGO2 | c.215G>T p.R72M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99595040; called by muse, mutect2
- AGPAT4 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as rs1454374642, COSV100210802; called by muse, mutect2, varscan2
- AGTPBP1 | c.2340G>A p.M780I (on ENST00000357081 / NM_001330701.2; = p.M740I on NM_015239.2) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1365644171, COSV100429102; called by muse, mutect2, varscan2
- AHDC1 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1354553377, COSV99898729; called by muse, mutect2, varscan2
- AIFM1 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs868066290, COSV99780649; called by muse, mutect2, varscan2
- AJM1 | c.2185A>G p.S729G | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV56034625; called by muse, mutect2, varscan2
- AKAP12 | c.2788G>A p.A930T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs375774812; called by muse, mutect2, varscan2
- AKAP6 | c.5123A>G p.K1708R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99797319; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 192/257 reads (75%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8L | c.1144C>A p.R382S | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101275695, COSV101275821; called by muse, mutect2, varscan2
- AKR1B1 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs577826776, COSV99605079; called by muse, mutect2, varscan2
- AKR1E2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs778184151, COSV53631026; called by muse, mutect2, varscan2
- AL441992.2 | c.659G>A p.C220Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100223302; called by muse, mutect2, varscan2
- AL592490.1 | c.95A>C p.H32P | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV69426259; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALG10B | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as rs777834111, COSV100439750, COSV58142763; called by muse, varscan2
- ALG10B | c.790T>C p.F264L | Missense Mutation (SNP) | VAF 166/456 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100439751; called by muse, varscan2
- ALK | c.4099C>A p.Q1367K | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV101200770; called by muse, mutect2, varscan2
- ALS2CL | c.2768T>C p.L923P | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014612; called by muse, mutect2, varscan2
- ALX4 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.262); catalogued as COSV100240774; called by muse, varscan2
- AMDHD1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs781422816, COSV99900145; called by muse, mutect2, varscan2
- AMELX | c.388del p.Q130Sfs*45 | Frame Shift Del (DEL) | VAF 48/127 reads (38%) | catalogued as COSV61630754; called by mutect2, pindel, varscan2
- ANKLE1 | c.242T>C p.L81P (on ENST00000394458; = p.L27P on NM_152363.6) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845685; called by muse, mutect2, varscan2
- ANKS1A | c.959del p.P320Hfs*25 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | catalogued as COSV64461548; called by mutect2, pindel, varscan2
- ANKS6 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as COSV62050254; called by muse, mutect2, varscan2
- ANLN | c.1544C>T p.T515M | Missense Mutation (SNP) | VAF 132/409 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs547427621, COSV56075844; called by muse, varscan2
- ANPEP | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 43/83 reads (52%) | catalogued as COSV100262475, COSV55590636; called by muse, mutect2
- AP1G1 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.075); catalogued as COSV100249924; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | catalogued as rs753029866; called by mutect2, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 24/37 reads (65%) | catalogued as rs770443312, COSV59961800; called by mutect2, pindel, varscan2
- AP4B1 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV99870440; called by muse, mutect2, varscan2
- APBA1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs759515322, COSV55231757, COSV55231856; called by muse, varscan2
- APBA1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.805); catalogued as rs1275599927, COSV99595224; called by muse, mutect2, varscan2
- APC | c.3700A>G p.S1234G | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57322217, COSV99964311; called by muse, mutect2, varscan2
- APC2 | c.793A>G p.T265A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52018449; called by muse, mutect2, varscan2
- APCDD1L | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs142388944; called by muse, mutect2, varscan2
- APOA4 | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1355734114, COSV100759221; called by muse, mutect2, varscan2
- APOBEC2 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1415911773, COSV55107808; called by muse, mutect2, varscan2
- APOBEC3F | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.926); catalogued as COSV100415075; called by muse, mutect2, varscan2
- ARAF | c.1721T>C p.L574P | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99282907; called by muse, mutect2
- ARCN1 | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99873342; called by muse, mutect2, varscan2
- ARCN1 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99873345; called by muse, mutect2, varscan2
- ARF1 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55254869; called by muse, mutect2, varscan2
- ARFGEF2 | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64216517; called by muse, mutect2, varscan2
- ARFGEF3 | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as rs1475400991, COSV99291990; called by muse, mutect2
- ARHGAP11B | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs770792015, COSV101451748; called by muse, mutect2, varscan2
- ARHGAP17 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 106/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99252683; called by muse, mutect2, varscan2
- ARHGAP28 | c.1781C>T p.T594M (on ENST00000383472 / NM_001366230.1; = p.T435M on NM_001010000.3) | Missense Mutation (SNP) | VAF 95/220 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs144213417, COSV51638114; called by muse, mutect2, varscan2
- ARHGAP35 | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs761081196, COSV101350591; called by muse, mutect2, varscan2
- ARHGAP4 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs781995523, COSV61686210; called by muse, mutect2, varscan2
- ARHGAP6 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.326); catalogued as COSV100496848; called by muse, mutect2, varscan2
- ARHGEF11 | c.3986C>T p.A1329V | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100168105; called by muse, mutect2, varscan2
- ARHGEF37 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs200439928, COSV100381830; called by muse, mutect2, varscan2
- ARID1A | c.6341del p.P2114Rfs*21 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as COSV61383086; called by mutect2, pindel, varscan2
- ARL13B | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV57398281; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.626del p.N209Ifs*9 | Frame Shift Del (DEL) | VAF 45/128 reads (35%) | catalogued as rs1295666772; called by mutect2, pindel, varscan2
- ARRDC1 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603420; called by muse, mutect2, varscan2
- ARRDC3 | c.614-1G>T p.X205_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV54364834; called by muse, mutect2, varscan2
- ARRDC5 | c.725G>A p.R242Q (on ENST00000381781; = p.R228Q on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs565313313, COSV67787728; called by muse, mutect2, varscan2
- ARSD | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1569085008, COSV66973324; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 66/154 reads (43%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASAP3 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV100369054; called by muse, mutect2, varscan2
- ASB2 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100279164; called by muse, mutect2, varscan2
- ASB2 | c.336G>A p.A112= | Splice Region (SNP) | VAF 14/38 reads (37%) | catalogued as rs773643047, COSV60114766; called by muse, mutect2, varscan2
- ASB7 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs774902537, COSV100234904; called by muse, mutect2, varscan2
- ASCC3 | c.5719C>T p.P1907S | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100976132; called by muse, mutect2, varscan2
- ASNSD1 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs1432628991, COSV53623902; called by muse, mutect2, varscan2
- ASPHD2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs149037223; called by muse, mutect2, varscan2
- ASPRV1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100208338; called by muse, mutect2, varscan2
- ASZ1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as rs113501399, COSV52914600; called by muse, mutect2, varscan2
- ATAT1 | c.1049G>A p.G350D (on ENST00000376485; = p.G338D on NM_001031722.4) | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99527608; called by muse, mutect2, varscan2
- ATF4 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100307482; called by muse, mutect2, varscan2
- ATF6 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV100908969; called by muse, mutect2, varscan2
- ATG2A | c.4651C>T p.R1551* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as rs1398367714, COSV65966560; called by muse, mutect2, varscan2
- ATG4A | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); catalogued as COSV57866597, COSV57872599; called by muse, mutect2, varscan2
- ATG9A | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100772393; called by muse, mutect2
- ATG9A | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100036629; called by muse, mutect2, varscan2
- ATP10A | c.3893G>T p.R1298M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100790709; called by muse, mutect2, varscan2
- ATP11A | c.2380G>A p.V794M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52111696; called by muse, mutect2, varscan2
- ATP1A2 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100767565; called by muse, mutect2, varscan2
- ATP2A3 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs781334265, COSV59227758; called by muse, mutect2, varscan2
- ATP2B3 | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV54847240; called by muse, mutect2
- ATP5IF1 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.253); catalogued as COSV99745945; called by muse, varscan2
- ATP5MF | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751859589, COSV99461509; called by muse, varscan2
- ATP6V0A1 | c.2341G>A p.A781T (on ENST00000343619 / NM_001378531.1; = p.A775T on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as COSV99230239; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1274A>G p.D425G | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV99313701; called by muse, varscan2
- ATP6V1C1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1455268921, COSV67777243, COSV67778043; called by muse, mutect2, varscan2
- ATP6V1C2 | c.790A>G p.M264V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV55360229; called by muse, mutect2
- ATP9A | c.1462T>C p.Y488H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.489); catalogued as COSV100124108; called by muse, mutect2, varscan2
- ATPSCKMT | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV99725726; called by muse, mutect2
- ATRX | c.7420C>T p.R2474C | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV64876551; called by muse, mutect2, varscan2
- ATXN1 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs375508636; called by muse, mutect2, varscan2
- AURKB | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as rs55871613, COSV60244554; called by muse, mutect2, varscan2
- AXIN1 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1047458992, COSV99249046; called by muse, mutect2, varscan2
- AXIN1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as rs764120241, COSV99249049, COSV99250452; called by muse, mutect2, varscan2
- AXIN1 | c.1116+1G>A p.X372_splice | Splice Site (SNP) | VAF 27/64 reads (42%) | catalogued as COSV51984731; called by muse, mutect2, varscan2
- B3GALT6 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.484); catalogued as COSV99767246; called by muse, mutect2, varscan2
- B3GAT1 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56996967; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BAG3 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs956429406, COSV64842020; called by muse, mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | catalogued as rs747119215; called by mutect2, pindel, varscan2
- BBX | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100360759; called by muse, mutect2
- BCAR3 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV99550010; called by muse, mutect2, varscan2
- BCL11B | c.2632G>A p.G878S (on ENST00000357195 / NM_001282237.2; = p.G807S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.27); catalogued as rs758918107, COSV61736277; called by muse, mutect2, varscan2
- BCL2L1 | c.362A>C p.Q121P | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100304568; called by muse, mutect2, varscan2
- BCL3 | c.1235del p.P412Lfs*70 | Frame Shift Del (DEL) | VAF 45/116 reads (39%) | catalogued as rs1371524592; called by mutect2, pindel, varscan2
- BCL9 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); catalogued as rs782395400, COSV52349284; called by muse, mutect2, varscan2
- BCL9L | c.3593del p.P1198Lfs*5 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | catalogued as COSV52684452; called by mutect2, pindel, varscan2
- BCORL1 | c.1951C>G p.H651D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99498126; called by muse, mutect2, varscan2
- BDKRB2 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs199803197, COSV100020815; called by muse, mutect2, varscan2
- BFSP1 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs550597037, COSV64902569; called by muse, mutect2, varscan2
- BHLHE23 | c.559G>T p.G187C (on ENST00000370346; = p.G203C on NM_080606.4) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100947565; called by muse, mutect2, varscan2
- BMPER | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as rs139762183, COSV51810723; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 38/115 reads (33%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOC | c.3164del p.P1055Hfs*20 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | catalogued as rs1559896461; called by mutect2, pindel, varscan2
- BOD1L1 | c.8063C>T p.A2688V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99238053; called by muse, mutect2, varscan2
- BPIFB2 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs930579273, COSV50063479, COSV50064657; called by muse, mutect2, varscan2
- BPIFB3 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV64957582; called by muse, mutect2, varscan2
- BRD1 | c.2545C>T p.R849C (on ENST00000216267 / NM_001349940.1; = p.R980C on NM_001304808.3) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs925602300, COSV53457405; called by muse, mutect2, varscan2
- BTBD2 | c.1547G>A p.G516D | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868834589, COSV99724444; called by muse, mutect2, varscan2
- BTNL3 | c.484del p.Q162Sfs*35 | Frame Shift Del (DEL) | VAF 28/186 reads (15%) | catalogued as COSV61564774; called by mutect2, pindel, varscan2
- BTNL8 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs776813203, COSV99180404; called by muse, mutect2, varscan2
- BUB3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs753417733, COSV64363817; called by muse, mutect2, varscan2
- C12orf42 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100171601; called by muse, mutect2, varscan2
- C19orf18 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs370086774; called by muse, mutect2, varscan2
- C22orf39 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs373255364; called by muse, mutect2, varscan2
- C2CD3 | c.1498A>G p.R500G | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58093028; called by muse, mutect2, varscan2
- C2CD5 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1471759162, COSV61724558; called by muse, mutect2, varscan2
- C3 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as rs766880159, COSV99835780; called by muse, mutect2, varscan2
- C5AR1 | c.541T>C p.Y181H | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100753922; called by muse, mutect2, varscan2
- C6orf15 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1562743845, COSV52538112; called by muse, mutect2, varscan2
- CA2 | c.440dup p.L147Ffs*7 | Frame Shift Ins (INS) | VAF 78/204 reads (38%) | catalogued as rs763603775; called by mutect2, varscan2
- CA6 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101077278; called by muse, mutect2, varscan2
- CABP2 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99590671; called by muse, mutect2, varscan2
- CACNA1A | c.7204C>T p.H2402Y | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.086); catalogued as COSV100800229; called by muse, mutect2, varscan2
- CACNA1C | c.5596T>C p.C1866R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100214173; called by muse, mutect2, varscan2
- CACNA1E | c.6469C>T p.R2157W (on ENST00000367573 / NM_001205293.3; = p.R2114W on NM_000721.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs749525291, COSV62387931; called by muse, mutect2, varscan2
- CACNA1I | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as COSV100358848; called by muse, mutect2, varscan2
- CACNA1I | c.4781G>A p.R1594Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1045204674, COSV100358855, COSV60816250; called by muse, mutect2, varscan2
- CAD | c.3512dup p.Q1172Tfs*37 | Frame Shift Ins (INS) | VAF 24/67 reads (36%) | catalogued as rs760688978; called by mutect2, varscan2
- CAD | c.6346C>T p.R2116W | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs779304281, COSV53025926; called by muse, mutect2, varscan2
- CADM2 | c.95T>C p.V32A (on ENST00000407528 / NM_001167674.2; = p.V34A on NM_153184.4) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.678); catalogued as COSV67374621; called by muse, mutect2, varscan2
- CALCR | c.1406A>G p.N469S (on ENST00000649521 / NM_001164737.2; = p.N453S on NM_001742.4) | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.477); catalogued as COSV64008157; called by muse, mutect2, varscan2
- CALHM1 | c.737G>A p.C246Y | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs749992074, COSV99588189; called by muse, mutect2, varscan2
- CAMKK1 | c.1337C>T p.T446M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1436312447, COSV99339863; called by muse, mutect2, varscan2
- CAMKV | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs199584164, COSV56555382; called by muse, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs201838505; called by mutect2, varscan2
- CAMTA2 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV100772273; called by muse, mutect2, varscan2
- CAPN12 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs45627633; called by muse, mutect2, varscan2
- CAPN15 | c.641del p.P214Qfs*73 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs1318388431; called by mutect2, varscan2
- CAPN3 | c.2458T>C p.Y820H | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99781975; called by muse, mutect2, varscan2
- CAPRIN2 | c.310dup p.L104Pfs*16 | Frame Shift Ins (INS) | VAF 47/176 reads (27%) | catalogued as rs1400902916; called by mutect2, pindel, varscan2
- CARD11 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as rs376539147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 29/60 reads (48%) | catalogued as rs765105588; called by mutect2, varscan2
- CASZ1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.014); catalogued as rs1412420306, COSV100680497; called by muse, mutect2, varscan2
- CASZ1 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100680501; called by muse, mutect2, varscan2
- CAVIN4 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs191289133, COSV56867210; called by muse, mutect2, varscan2
- CBLN3 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99249232; called by muse, varscan2
- CBR1 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99289357; called by muse, mutect2, varscan2
- CCAR2 | c.1185T>A p.D395E | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100414450; called by muse, mutect2
- CCBE1 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as CM134168, COSV101480316; called by muse, mutect2, varscan2
- CCDC116 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV99488778; called by muse, varscan2
- CCDC116 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.445); catalogued as COSV99488779, COSV99489010; called by muse, varscan2
- CCDC124 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV101506476; called by muse, mutect2, varscan2
- CCDC144A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1365470382, COSV100501884; called by muse, varscan2
- CCDC144A | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.418); catalogued as COSV61404142; called by muse, varscan2
- CCDC173 | c.968A>T p.E323V | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101506272; called by muse, mutect2, varscan2
- CCDC180 | c.1619A>G p.H540R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV100826490; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 116/219 reads (53%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC183 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1461461863, COSV100565875; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 54/122 reads (44%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC39 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 136/367 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99866648; called by muse, mutect2, varscan2
- CCL1 | c.46A>G p.M16V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV99861642; called by mutect2, varscan2
- CCNY | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1447460317, COSV55185109; called by muse, mutect2, varscan2
- CCR5 | c.236del p.F79Sfs*26 | Frame Shift Del (DEL) | VAF 72/230 reads (31%) | catalogued as rs1444201344, COSV52751196; called by mutect2, pindel, varscan2
- CCR6 | c.239T>G p.M80R | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59475061; called by muse, mutect2, varscan2
- CCS | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV100039672; called by muse, mutect2, varscan2
- CCT6A | c.820del p.I274* | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs1482449902; called by mutect2, pindel, varscan2
- CD101 | c.761G>A p.W254* | Nonsense Mutation (SNP) | VAF 71/152 reads (47%) | catalogued as COSV99868923; called by muse, mutect2, varscan2
- CDC34 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99296200, COSV99296211; called by muse, mutect2, varscan2
- CDC42BPA | c.2995G>A p.G999R (on ENST00000334218 / NM_001366019.2; = p.G986R on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100503346; called by muse, mutect2, varscan2
- CDH10 | c.1577del p.F526Sfs*3 | Frame Shift Del (DEL) | VAF 40/90 reads (44%) | catalogued as rs1209448007; called by mutect2, varscan2
- CDH11 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs776736292, COSV51766937; called by muse, mutect2, varscan2
- CDH23 | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs111033489, COSV99818148; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH9 | c.695A>G p.Y232C | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753887521, COSV99141139; called by muse, mutect2, varscan2
- CDHR5 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100363159; called by muse, mutect2, varscan2
- CDK13 | c.3095G>A p.G1032D | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs1259628040, COSV99474847; called by muse, varscan2
- CDKAL1 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV99213668, COSV99214558; called by muse, mutect2, varscan2
- CDKL3 | c.1772del p.F591Sfs*9 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs753494539; called by mutect2, varscan2
- CDR1 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 167/436 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs878978859, COSV65164241; called by muse, mutect2, varscan2
- CEACAM5 | c.140_141insT p.E47Dfs*25 | Frame Shift Ins (INS) | VAF 39/118 reads (33%) | catalogued as COSV99703672; called by mutect2, pindel, varscan2
- CEBPZ | c.1646A>G p.Y549C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143633668; called by muse, mutect2, varscan2
- CELF2 | c.190G>A p.G64R (on ENST00000416382 / NM_001025077.3; = p.G71R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202642426, COSV100256705, COSV59973961; called by muse, mutect2, varscan2
- CELF4 | c.1000T>C p.S334P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs751100448, COSV100610832; called by muse, mutect2, varscan2
- CELSR2 | c.2099T>C p.V700A | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99602777; called by muse, mutect2, varscan2
- CELSR2 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs987302804, COSV99602779; called by muse, mutect2, varscan2
- CELSR3 | c.3856C>T p.R1286C | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1418729394, COSV99372152; called by muse, mutect2, varscan2
- CELSR3 | c.1604_1605del p.V535Afs*36 | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | catalogued as rs1476394679; called by pindel, varscan2
- CENPBD1 | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99240103; called by muse, mutect2, varscan2
- CENPF | c.7612G>C p.V2538L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs750934379, COSV100871393; called by muse, mutect2, varscan2
- CENPT | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99534735; called by muse, mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 77/232 reads (33%) | catalogued as rs769310263; called by mutect2, pindel, varscan2
- CEP120 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs879077864, COSV100070682; called by muse, mutect2
- CEP131 | c.3117-1G>A p.X1039_splice (on ENST00000269392 / NM_001319228.2; = p.X1036_splice on NM_014984.4) | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as COSV99487704; called by muse, mutect2, varscan2
- CEP170B | c.1639G>A p.A547T (on ENST00000453495; = p.A476T on NM_015005.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs750638092, COSV101371363, COSV69023713; called by muse, mutect2, varscan2
- CEP170B | c.1892T>C p.L631P (on ENST00000453495; = p.L560P on NM_015005.3) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV101371364; called by muse, mutect2, varscan2
- CERS3 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV52573861; called by muse, mutect2
- CERT1 | c.1347G>T p.E449D (on ENST00000405807 / NM_001130105.1; = p.E321D on NM_005713.3) | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99782671; called by muse, mutect2, varscan2
- CFAP20 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs781222045, COSV99343327; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.640del p.T214Pfs*40 | Frame Shift Del (DEL) | VAF 24/220 reads (11%) | catalogued as COSV51593519; called by mutect2, pindel, varscan2
- CFAP44 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs113101974, COSV55611403; called by muse, mutect2, varscan2
- CFAP45 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs760190244, COSV100928411; called by muse, mutect2, varscan2
- CFAP61 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99842537; called by muse, mutect2
- CFAP69 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV100289652, COSV60184488; called by muse, mutect2, varscan2
- CFHR3 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 113/290 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs1440187744, COSV66401591; called by muse, mutect2, varscan2
- CFTR | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.123); catalogued as COSV99133560; called by muse, mutect2, varscan2
- CGNL1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs921849547, COSV99847148; called by muse, mutect2
- CHD1 | c.3237+2T>C p.X1079_splice | Splice Site (SNP) | VAF 15/157 reads (10%) | catalogued as COSV99398920; called by muse, mutect2
- CHD4 | c.2197G>A p.D733N (on ENST00000357008 / NM_001363606.2; = p.D746N on NM_001273.5) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as COSV58901204; called by muse, mutect2, varscan2
- CHD8 | c.5689C>T p.R1897W (on ENST00000646647 / NM_001170629.2; = p.R1618W on NM_020920.4) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100765230; called by muse, mutect2, varscan2
- CHEK1 | c.676del p.T226Hfs*14 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | catalogued as rs757716680, COSV54024545; called by mutect2, varscan2
- CHERP | c.1966G>C p.A656P | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as COSV99549870; called by muse, mutect2, varscan2
- CHERP | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.996); catalogued as COSV99549874; called by muse, mutect2, varscan2
- CHFR | c.1516G>A p.A506T (on ENST00000432561 / NM_001161345.1; = p.A465T on NM_018223.2) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs746554223, COSV57171673; called by muse, mutect2, varscan2
- CHIT1 | c.1325del p.A442Gfs*36 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as CM074096, COSV55148534, COSV55148908; called by mutect2, pindel, varscan2
- CHIT1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs369594904; called by muse, mutect2, varscan2
- CHL1 | c.3047-2A>G p.X1016_splice (on ENST00000397491 / NM_001253387.1; = p.X1032_splice on NM_006614.4) | Splice Site (SNP) | VAF 10/86 reads (12%) | catalogued as COSV99849667; called by muse, mutect2
- CHRNA4 | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs121912282, COSV100937303, COSV64719704; ClinVar: not provided / uncertain significance / likely benign; called by muse, mutect2, varscan2
- CHRNA7 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1296944199, COSV100180621; called by muse, mutect2, varscan2
- CHST15 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as rs200319997, COSV60559964; called by muse, mutect2, varscan2
- CHST4 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs929551127, COSV58296928; called by muse, mutect2, varscan2
- CIITA | c.1652G>A p.G551D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.415); catalogued as COSV60857123; called by muse, mutect2, varscan2
- CIT | c.5564G>A p.R1855H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs763157071, COSV55888931; called by muse, mutect2, varscan2
- CKAP5 | c.926A>C p.N309T | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV100370250; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.89_90del p.V30Dfs*13 | Frame Shift Del (DEL) | VAF 56/172 reads (33%) | catalogued as rs1462523516; called by pindel, varscan2
- CLASP1 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs758253235, COSV99752172; called by muse, mutect2, varscan2
- CLCN7 | c.213G>A p.P71= | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as rs762701523, COSV99246761; called by muse, mutect2, varscan2
- CLDN15 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.222); catalogued as COSV100385151; called by muse, mutect2, varscan2
- CLEC4F | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99713450; called by muse, mutect2, varscan2
- CLIP2 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99790798; called by muse, mutect2, varscan2
- CLK3 | c.725G>A p.R242Q (on ENST00000395066 / NM_001130028.1; = p.R94Q on NM_003992.4) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs1411782408, COSV61413962, COSV61414596; called by muse, mutect2, varscan2
- CLMP | c.12_14del p.L9del | In Frame Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs1211939986; called by pindel, varscan2
- CLNK | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as COSV57014975; called by muse, mutect2, varscan2
- CLTCL1 | c.3334G>A p.A1112T | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99594318; called by muse, mutect2, varscan2
- CMTM1 | c.180del p.F60Lfs*3 (on ENST00000457188 / NM_181269.3; = p.F177Lfs*3 on NM_052999.4) | Frame Shift Del (DEL) | VAF 60/188 reads (32%) | catalogued as rs773521289; called by mutect2, varscan2
- CNBD2 | c.394A>G p.M132V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV62588022; called by muse, mutect2, varscan2
- CNKSR1 | c.1535del p.P512Hfs*58 (on ENST00000374253 / NM_001297647.2; = p.P505Hfs*58 on NM_006314.3) | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as rs753922055; called by mutect2, pindel, varscan2
- CNKSR2 | c.3065C>T p.S1022F | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.427); catalogued as rs144451192, COSV101069848; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTLN | c.2548A>G p.I850V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV52074489; called by muse, mutect2
- CNTLN | c.4043A>G p.E1348G | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as COSV52078751; called by muse, mutect2, varscan2
- CNTN5 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs1279173094, COSV99671333; called by muse, mutect2, varscan2
- COA6 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV100784522; called by muse, mutect2, varscan2
- COA8 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1285531548, COSV56028545; called by muse, mutect2, varscan2
- COL14A1 | c.3992T>C p.F1331S | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99917528; called by muse, mutect2
- COL16A1 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs41263975; called by muse, mutect2, varscan2
- COL18A1 | c.4874T>C p.L1625P (on ENST00000359759 / NM_130444.3; = p.L1390P on NM_030582.4) | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100229034; called by muse, mutect2, varscan2
- COL19A1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as rs1268966250, COSV100504775; called by muse, mutect2
- COL27A1 | c.2929G>A p.V977M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs143200559; called by muse, mutect2, varscan2
- COL4A3 | c.577C>G p.P193A | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.695); catalogued as COSV101169732; called by muse, mutect2, varscan2
- COL5A1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.935); catalogued as rs776904091, COSV65665757; called by muse, mutect2, varscan2
- COL6A1 | c.1185C>T p.G395= | Splice Region (SNP) | VAF 14/31 reads (45%) | catalogued as rs770958800, COSV100719810; called by muse, mutect2, varscan2
- COL6A2 | c.137A>G p.H46R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as COSV100152779; called by muse, mutect2, varscan2
- COL6A3 | c.3199G>A p.V1067M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148175795; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.1657A>G p.I553V | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1447257982, COSV100649636; called by muse, mutect2, varscan2
- COL7A1 | c.1305del p.W435* | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as COSV60392288; called by mutect2, pindel, varscan2
- COL9A1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs773143381, COSV61833606, COSV61835935; called by muse, mutect2, varscan2
- COL9A1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as rs1386121681, COSV100610778; called by muse, mutect2, varscan2
- COMP | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1162910542, COSV99721252; called by muse, mutect2, varscan2
- COP1 | c.2116A>G p.R706G | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100442463; called by muse, mutect2, varscan2
- COP1 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as rs749542797, COSV58179083; called by muse, mutect2, varscan2
- COPS2 | c.42_44del p.E14del | In Frame Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1566888918; called by pindel, varscan2
- CORO7 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as rs761999840, COSV99226989; called by muse, mutect2, varscan2
- COX6A2 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs978580253, COSV54931945; called by muse, mutect2, varscan2
- COX8C | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.447); catalogued as rs752878344, COSV56387882; called by muse, mutect2, varscan2
- CPAMD8 | c.3430G>A p.E1144K (on ENST00000651564; = p.E1097K on NM_015692.5) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs373100801; called by muse, mutect2, varscan2
- CPNE6 | c.683A>G p.Y228C | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99392994; called by muse, mutect2, varscan2
- CPSF7 | c.214T>C p.Y72H (on ENST00000394888 / NM_001136040.4; = p.Y115H on NM_024811.4) | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1412448339, COSV100466874; called by muse, mutect2, varscan2
- CPT1B | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs571187466, COSV100376425; called by muse, mutect2, varscan2
- CPVL | c.794del p.K265Sfs*11 | Frame Shift Del (DEL) | VAF 47/145 reads (32%) | catalogued as rs1562753933; called by pindel, varscan2
- CPVL | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99605140; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel, varscan2
- CRB1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.863); catalogued as rs116347915, COSV100958159; called by muse, mutect2, varscan2
- CRB2 | c.1634G>A p.C545Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1339326644, COSV100749468; called by muse, mutect2, varscan2
- CRB2 | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs765515914, COSV63504342; called by muse, mutect2
- CREB3L1 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs375217169; called by muse, mutect2, varscan2
- CREB3L1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as rs771754544, COSV55832399; called by muse, mutect2, varscan2
- CREBZF | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs777311621, COSV99476046; called by muse, mutect2
- CRISPLD2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs199608437, COSV52282578; called by muse, mutect2, varscan2
- CRYBG3 | c.6437C>T p.A2146V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV99476445; called by muse, mutect2
- CSAD | c.310G>A p.G104R (on ENST00000444623 / NM_001244705.2; = p.G131R on NM_015989.5) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs775973649, COSV57242308; called by muse, mutect2, varscan2
- CSMD2 | c.5257G>A p.V1753M | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99584178; called by muse, mutect2, varscan2
- CSMD2 | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.294); catalogued as rs191240645; called by muse, mutect2, varscan2
- CSMD2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs376307224; called by muse, mutect2, varscan2
- CSMD2 | c.282G>A p.T94= | Splice Region (SNP) | VAF 47/87 reads (54%) | catalogued as rs745833177, COSV53950507; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSNK1A1L | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs759977373, COSV65789302, COSV65789894, COSV65790611; called by muse, mutect2, varscan2
- CSPG4 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs573119481, COSV57894893; called by muse, mutect2, varscan2
- CTAGE15 | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 66/969 reads (7%) | catalogued as rs530134179, COSV101372095; called by muse, mutect2
- CTAGE6 | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); catalogued as COSV101417791; called by muse, mutect2, varscan2
- CTDP1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1211200091, COSV99309985; called by muse, mutect2, varscan2
- CTNNA3 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV101044631; called by muse, mutect2, varscan2
- CTNND1 | c.2326A>G p.I776V (on ENST00000399050 / NM_001085458.2; = p.I770V on NM_001331.3) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1190749521, COSV100649686; called by muse, varscan2
- CTPS1 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs756273124, COSV65452470; called by muse, mutect2, varscan2
- CUL2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs140997018; called by muse, mutect2, varscan2
- CUX2 | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99918244; called by muse, mutect2, varscan2
- CXCR5 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99418317; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP20A1 | c.1369A>G p.T457A | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV61909491; called by muse, varscan2
- CYP2A7 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV52498174, COSV99393569; called by muse, mutect2
- CYP2J2 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV64606269; called by muse, mutect2, varscan2
- CYP46A1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as rs762967586, COSV99952325; called by muse, mutect2, varscan2
- CYP4A11 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs199678286, COSV60223594, COSV60226073; called by muse, mutect2, varscan2
- CYP4B1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs752316206, COSV54721991; called by muse, mutect2, varscan2
- DAGLA | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442295701, COSV99943839; called by muse, mutect2, varscan2
- DAGLA | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs754533394, COSV99943841; called by muse, mutect2, varscan2
- DCAF1 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100244013, COSV60046635; called by muse, mutect2, varscan2
- DCAF12L2 | c.70T>A p.S24T | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV100758404; called by muse, mutect2, varscan2
- DCAF6 | c.2440G>A p.E814K (on ENST00000312263 / NM_001349778.1; = p.E834K on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV100393706; called by muse, mutect2, varscan2
- DCST1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1234083134, COSV55051803; called by muse, mutect2, varscan2
- DCST2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760731516, COSV99791552; called by muse, mutect2, varscan2
- DDX19B | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 54/146 reads (37%) | catalogued as rs779047963, COSV99849725; called by muse, mutect2, varscan2
- DDX24 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.096); catalogued as COSV100427780; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX31 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs367667543; called by muse, mutect2, varscan2
- DDX4 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471377290, COSV61754582; called by muse, mutect2, varscan2
- DDX5 | c.1777T>C p.Y593H | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56749099; called by muse, mutect2, varscan2
- DEDD2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.865); catalogued as rs535277377, COSV60141567; called by muse, mutect2, varscan2
- DENND1C | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs754909074, COSV101200125; called by muse, mutect2, varscan2
- DENND4B | c.9G>T p.E3D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100338707; called by muse, mutect2
- DENND5A | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100063794; called by muse, mutect2
- DEPDC5 | c.2798C>T p.A933V (on ENST00000400246; = p.A1002V on NM_014662.5) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1262294738, COSV99834007; called by muse, mutect2, varscan2
- DGKA | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs768940177, COSV100092479, COSV100092486; called by muse, mutect2, varscan2
- DGKB | c.2156G>A p.G719D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99335299; called by muse, mutect2, varscan2
- DGKH | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs753372667, COSV54931763; called by muse, mutect2, varscan2
- DGKZ | c.1344_1345insC p.K449Qfs*17 (on ENST00000454345 / NM_001105540.2; = p.K261Qfs*17 on NM_003646.4) | Frame Shift Ins (INS) | VAF 38/118 reads (32%) | catalogued as COSV58984107, COSV58987748; called by mutect2, pindel, varscan2
- DGLUCY | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs753588534, COSV56370537; called by muse, mutect2, varscan2
- DHRS13 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs1432703890, COSV101128782; called by muse, mutect2, varscan2
- DHX38 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs753722533, COSV51696673; called by muse, mutect2, varscan2
- DHX38 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 27/51 reads (53%) | catalogued as COSV51697928; called by muse, mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs771360300; called by mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 82/182 reads (45%) | catalogued as rs755069320; called by mutect2, varscan2
- DIDO1 | c.5591C>T p.T1864M | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs376942853, COSV56616559; called by muse, mutect2, varscan2
- DISP2 | c.1825C>A p.L609M | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.487); catalogued as COSV99139634; called by muse, mutect2, varscan2
- DKKL1 | c.200del p.G67Afs*2 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs1568591946, COSV55561610, COSV99678601; called by mutect2, pindel, varscan2
- DKKL1 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV99678558; called by muse, mutect2, varscan2
- DLC1 | c.4441A>G p.T1481A (on ENST00000276297 / NM_001348081.2; = p.T1044A on NM_006094.5) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1328478252, COSV99360268; called by muse, mutect2, varscan2
- DLEC1 | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs752782524, COSV100341101; called by muse, mutect2, varscan2
- DLG2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.671); catalogued as rs1414599025, COSV54646625; called by muse, mutect2, varscan2
- DLL1 | c.845dup p.L283Pfs*14 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs760008381; called by mutect2, varscan2
- DMBT1 | c.7357G>A p.V2453M (on ENST00000338354 / NM_001377530.1; = p.V1696M on NM_004406.3) | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs372434439; called by muse, varscan2
- DMKN | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1383141492, COSV60087687; called by muse, mutect2
- DMKN | c.403del p.V135Cfs*52 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as COSV60087927; called by mutect2, pindel, varscan2
- DMXL1 | c.7174C>T p.R2392C | Missense Mutation (SNP) | VAF 170/483 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs376608292; called by muse, mutect2, varscan2
- DNAAF3 | c.580C>A p.L194M (on ENST00000524407 / NM_001256715.2; = p.L241M on NM_178837.4) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100787805; called by muse, mutect2, varscan2
- DNAH10 | c.5230G>A p.A1744T (on ENST00000409039; = p.A1683T on NM_207437.3) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV101291852; called by muse, mutect2, varscan2
- DNAH17 | c.9469C>T p.P3157S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568083620, COSV67754343; called by muse, mutect2, varscan2
- DNAH5 | c.13843C>T p.R4615C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771613197, COSV54239919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 106/254 reads (42%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH8 | c.5065A>G p.S1689G | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100542617; called by muse, mutect2
- DNAH8 | c.11062G>A p.G3688R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561888205, COSV100542620; called by muse, mutect2, varscan2
- DNAH9 | c.5130G>A p.W1710* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as rs772923356, COSV99303023; called by muse, mutect2, varscan2
- DNAI3 | c.1521A>G p.I507M | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.372); catalogued as COSV99641176; called by muse, mutect2, varscan2
- DNAJB13 | c.475del p.I159Lfs*8 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | catalogued as rs754363435; called by mutect2, pindel, varscan2
- DNAJC28 | c.617A>C p.D206A | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074608; called by muse, mutect2, varscan2
- DNAJC8 | c.228G>C p.R76S | Missense Mutation (SNP) | VAF 189/469 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV99745944; called by muse, mutect2, varscan2
- DNAL1 | c.218G>T p.R73M | Missense Mutation (SNP) | VAF 246/624 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100225690, COSV100225930; called by muse, mutect2, varscan2
- DNER | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.321); catalogued as rs769511648, COSV100518020; called by muse, mutect2, varscan2
- DOCK5 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99375765; called by muse, mutect2, varscan2
- DOCK5 | c.4036G>A p.A1346T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52413390; called by muse, mutect2, varscan2
- DOCK8 | c.2614A>G p.T872A | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV66620092; called by muse, mutect2, varscan2
- DOP1A | c.2227T>A p.Y743N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.536); catalogued as COSV99380577; called by muse, mutect2, varscan2
- DPF2 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52889284; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DRD5 | c.615G>T p.E205D | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100431448, COSV58580724; called by muse, mutect2
- DSC1 | c.2539G>A p.V847I | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.392); catalogued as rs771621552, COSV99936958; called by muse, mutect2
- DSE | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528236; called by muse, mutect2, varscan2
- DSG2 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs397516705, COSV99852584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.2092T>C p.S698P | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV101131149; called by muse, mutect2, varscan2
- DSTYK | c.2387T>C p.L796S | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100904408; called by muse, mutect2, varscan2
- DTX4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs372277661; called by muse, mutect2, varscan2
- DTX4 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV57090770; called by muse, mutect2, varscan2
- DUOX2 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100545668; called by muse, mutect2, varscan2
- DUSP12 | c.478T>C p.W160R | Missense Mutation (SNP) | VAF 160/414 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV100909651; called by muse, varscan2
- DYNC1H1 | c.3994G>A p.V1332I | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1567005720, COSV100794155; called by muse, mutect2, varscan2
- DYNC2H1 | c.5000T>C p.L1667P | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517068; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 52/124 reads (42%) | catalogued as rs751377941; called by mutect2, varscan2
- DYNC2I1 | c.3044G>A p.G1015D | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as COSV68104809, COSV68105982; called by muse, mutect2, varscan2
- ECH1 | c.51G>A p.R17= | Splice Region (SNP) | VAF 14/48 reads (29%) | catalogued as COSV55489226; called by muse, mutect2, varscan2
- ECHS1 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV63906846; called by muse, mutect2
- EDC4 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs546531673, COSV62766047; called by muse, mutect2, varscan2
- EDEM1 | c.1055A>T p.N352I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99848944; called by muse, mutect2, varscan2
- EDEM3 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs958690854, COSV100544748; called by muse, mutect2, varscan2
- EDRF1 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 94/230 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs761170508, COSV61763436; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV56181878; called by muse, mutect2, varscan2
- EEF2K | c.586del p.E196Rfs*22 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | catalogued as rs1567276794; called by mutect2, pindel, varscan2
- EEPD1 | c.711del p.T239Pfs*23 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as COSV54196001; called by pindel, varscan2
- EFCAB5 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.042); catalogued as COSV100299607; called by muse, mutect2, varscan2
- EFHC2 | c.1397T>C p.V466A | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101375429; called by muse, mutect2, varscan2
- EFL1 | c.3290G>A p.R1097Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319348019, COSV51607191; called by muse, mutect2, varscan2
- EFL1 | c.3139C>A p.L1047M | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51606244; called by muse, mutect2, varscan2
- EFNB3 | c.13dup p.H5Pfs*36 | Frame Shift Ins (INS) | VAF 8/15 reads (53%) | catalogued as rs745309220; called by mutect2, varscan2
- EGR3 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57832979; called by muse, mutect2, varscan2
- EHBP1 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs750441921, COSV99859654; called by muse, mutect2, varscan2
- EHD2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV54406925; called by muse, mutect2, varscan2
- EIF2AK4 | c.2567del p.L856Wfs*7 | Frame Shift Del (DEL) | VAF 61/160 reads (38%) | catalogued as rs35250897; called by mutect2, pindel, varscan2
- EIF3I | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100557068; called by muse, mutect2, varscan2
- EIF4A3 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99483908; called by muse, mutect2, varscan2
- ELAC2 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs148819805; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELAC2 | c.1432A>G p.S478G | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100568301; called by muse, mutect2, varscan2
- ELAPOR1 | c.2941C>T p.L981F | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100884395; called by muse, mutect2, varscan2
- ELFN2 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as rs758429117, COSV101297445; called by muse, mutect2, varscan2
- ELK1 | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 100/234 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901791; called by muse, varscan2
- ELL | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99442597; called by muse, mutect2, varscan2
- ELL2 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 73/200 reads (37%) | catalogued as COSV52981357, COSV99427073; called by muse, mutect2, varscan2
- ELMO3 | c.1967T>C p.L656P (on ENST00000652269; = p.L603P on NM_024712.5) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100440591; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 37/86 reads (43%) | catalogued as rs766700925; called by mutect2, varscan2
- ELOB | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99241197; called by muse, mutect2
- EMILIN1 | c.1576del p.E526Rfs*35 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as COSV53153225; called by mutect2, pindel, varscan2
- ENDOG | c.504G>A p.V168= | Splice Region (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100778189; called by muse, mutect2, varscan2
- ENOX2 | c.1276G>A p.D426N (on ENST00000338144 / NM_001382520.1; = p.D397N on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 184/399 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157780180, COSV57659691; called by muse, mutect2, varscan2
- ENPP7 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs201532960; called by muse, mutect2, varscan2
- ENTPD4 | c.488A>T p.H163L | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100652463; called by muse, mutect2
- ENY2 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV53456947; called by muse, mutect2, varscan2
- EP300 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as rs770254783, COSV99606986; called by muse, mutect2, varscan2
- EP300 | c.7144A>G p.M2382V | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV99606988; called by muse, mutect2
- EP400 | c.5A>G p.H2R | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as COSV100200038; called by muse, mutect2, varscan2
- EPB41L4A | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs528031482, COSV99812389; called by muse, mutect2, varscan2
- EPHA2 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.36); catalogued as rs755908156, COSV100625977; called by muse, mutect2, varscan2
- EPHA2 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs767568653, COSV100625978; called by muse, varscan2
- EPHA6 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1416212958, COSV67568195, COSV67586637; called by muse, mutect2, varscan2
- EPHX4 | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1450233465, COSV64889491; called by muse, mutect2, varscan2
- EPS15L1 | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50168775; called by muse, mutect2, varscan2
- ERF | c.1569del p.L525Sfs*6 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | catalogued as rs1366176199; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ERN1 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335737939, COSV70502231; called by muse, mutect2, varscan2
- ERN2 | c.2320del p.Q774Rfs*35 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs1567242682; called by mutect2, pindel, varscan2
- ESYT2 | c.901C>T p.R301W (on ENST00000613624; = p.R225W on NM_020728.3) | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752780690, COSV51748574; called by muse, mutect2, varscan2
- ETS2 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs981053782, COSV62872936; called by muse, mutect2, varscan2
- ETV4 | c.399del p.R134Dfs*30 | Frame Shift Del (DEL) | VAF 40/88 reads (45%) | catalogued as rs745944421, COSV60043782; called by mutect2, varscan2
- EVC | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1361442490, COSV53832386; called by muse, mutect2
- EXOC3L4 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs772349414, COSV101197534; called by muse, mutect2, varscan2
- EZHIP | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100539417; called by muse, mutect2, varscan2
- F2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.406); catalogued as COSV100319252; called by muse, mutect2, varscan2
- F2 | c.1484C>T p.A495V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100319254; called by muse, mutect2, varscan2
- F9 | c.1187G>A p.C396Y | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852273, CM940679, CM940680, CM990578, COSV99496170; called by muse, mutect2, varscan2
- FAM110D | c.616G>C p.G206R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs763203514, COSV100957611; called by mutect2, varscan2
- FAM160B2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.072); catalogued as rs201195171; called by muse, mutect2, varscan2
- FAM171A1 | c.2616G>T p.K872N | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65316103; called by muse, mutect2, varscan2
- FAM171A1 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV65313561; called by muse, mutect2, varscan2
- FAM193A | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100218392; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM216B | c.220+1G>A p.X74_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100573028; called by muse, mutect2
- FAM219A | c.492del p.K165Sfs*3 (on ENST00000445726; = p.K148Sfs*3 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs760074479; called by mutect2, pindel, varscan2
- FAM43A | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100316321; called by muse, mutect2, varscan2
- FAM43A | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV100316323; called by muse, mutect2, varscan2
- FAM47B | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs780975161, COSV61454531; called by muse, mutect2, varscan2
- FAM71A | c.1035_1036insT p.G346Wfs*73 | Frame Shift Ins (INS) | VAF 19/62 reads (31%) | catalogued as COSV99674274; called by mutect2, pindel, varscan2
- FAM81B | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs202064996, COSV51980413, COSV51987400; called by muse, mutect2, varscan2
- FAM83B | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs766774691, COSV60919265; called by muse, mutect2, varscan2
- FAM9B | c.446G>T p.R149I | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as COSV100510860, COSV59119846; called by muse, mutect2, varscan2
- FAP | c.1730C>T p.T577I | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99501483; called by muse, mutect2, varscan2
- FAR2 | c.529del p.I177Sfs*8 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | catalogued as rs757443519; called by mutect2, varscan2
- FARP1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.454); catalogued as rs774942512, COSV60337526; called by muse, mutect2, varscan2
- FARP2 | c.1003_1005del p.F335del | In Frame Del (DEL) | VAF 42/122 reads (34%) | catalogued as rs772582885; called by pindel, varscan2
- FARSB | c.793del p.I265* | Frame Shift Del (DEL) | VAF 53/176 reads (30%) | catalogued as COSV56049067; called by mutect2, pindel, varscan2
- FASN | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1260842268, COSV60754743; called by muse, mutect2, varscan2
- FASTKD3 | c.428dup p.D144Gfs*3 | Frame Shift Ins (INS) | VAF 70/182 reads (38%) | catalogued as rs773607911; called by mutect2, varscan2
- FAT3 | c.12004C>T p.R4002C | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53109982; called by muse, mutect2, varscan2
- FAT4 | c.7223C>T p.S2408F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs1278482803, COSV100626827; called by muse, mutect2, varscan2
- FAT4 | c.11637T>A p.C3879* | Nonsense Mutation (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100626830; called by muse, mutect2, varscan2
- FBL | c.841T>C p.S281P | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV99695083; called by muse, mutect2, varscan2
- FBN2 | c.5708G>A p.C1903Y | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52513106; called by muse, mutect2, varscan2
- FBXL19 | c.1268C>A p.P423H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as COSV100608484; called by muse, mutect2, varscan2
- FBXL2 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99371508; called by muse, mutect2, varscan2
- FBXL2 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs151236863, COSV99371509; called by muse, mutect2, varscan2
- FBXL7 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs375745885; called by muse, varscan2
- FBXL7 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100308779, COSV61651948; called by muse, mutect2, varscan2
- FBXO22 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs757686717, COSV57617254; called by muse, varscan2
- FBXO24 | c.593G>A p.R198H (on ENST00000241071 / NM_033506.3; = p.R236H on NM_012172.5) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs578251894, COSV53825046; called by muse, mutect2, varscan2
- FBXO41 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.469); catalogued as COSV99720757; called by muse, mutect2, varscan2
- FCGBP | c.8786C>T p.A2929V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as rs758063805; called by mutect2, varscan2
- FCGBP | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs752580756; called by muse, mutect2, varscan2
- FCRL3 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 99/226 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.085); catalogued as rs753184362, COSV63842572; called by muse, mutect2, varscan2
- FCRL4 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.15); catalogued as rs770243398, COSV99619088; called by muse, mutect2, varscan2
- FEM1A | c.998del p.G333Afs*31 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as COSV54163812; called by mutect2, pindel, varscan2
- FER1L6 | c.3816del p.N1273Tfs*23 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as COSV67551413; called by mutect2, pindel, varscan2
- FGFR1 | c.448C>T p.P150S (on ENST00000447712 / NM_023110.3; = p.P61S on NM_023105.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs746094709, COSV58334457; called by muse, mutect2, varscan2
- FGFR3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1333699127, COSV99599834; called by muse, mutect2, varscan2
- FGFRL1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV99294386; called by muse, mutect2, varscan2
- FGFRL1 | c.1454A>T p.H485L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as rs1434034079, COSV53258165; called by muse, varscan2
- FHL5 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs754828656, COSV58738983, COSV58740066; called by muse, mutect2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 38/90 reads (42%) | catalogued as rs777980924; called by mutect2, varscan2
- FHOD3 | c.3661C>A p.H1221N (on ENST00000359247 / NM_001281739.3; = p.H1238N on NM_025135.5) | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV99939632; called by muse, mutect2
- FIBCD1 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769443515, COSV99446514; called by muse, mutect2
- FIBCD1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); catalogued as rs369690143, COSV99446724; called by muse, mutect2, varscan2
- FIGN | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.932); catalogued as COSV100291214; called by muse, mutect2, varscan2
- FILIP1L | c.890C>T p.T297M (on ENST00000354552 / NM_182909.3; = p.T57M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as COSV100496039; called by muse, mutect2
- FKBP9 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); catalogued as rs751761819; called by muse, mutect2, varscan2
- FLCN | c.23G>A p.C8Y | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99549988; called by muse, mutect2, varscan2
- FLG2 | c.4547C>T p.T1516I | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs775651189, COSV101165529; called by muse, mutect2
- FLII | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57496237; called by muse, mutect2, varscan2
- FLT1 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV56729610, COSV99146772; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as COSV56098414; called by mutect2, pindel, varscan2
- FMN2 | c.223T>C p.F75L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100141935; called by muse, mutect2, varscan2
- FMN2 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV100141939, COSV60443189; called by muse, mutect2, varscan2
- FMNL2 | c.1673_1674insAC p.P560Lfs*29 | Frame Shift Ins (INS) | VAF 35/91 reads (38%) | catalogued as rs766789329; called by mutect2, pindel, varscan2
- FMO5 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.239); catalogued as COSV54206661; called by muse, mutect2, varscan2
- FNDC3A | c.35A>T p.Q12L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV101001121; called by muse, mutect2, varscan2
- FOXJ1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs995230360, COSV99486469; called by muse, mutect2, varscan2
- FOXJ2 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV50818769; called by muse, mutect2, varscan2
- FOXJ3 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 180/414 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs377432876; called by mutect2, varscan2
- FOXK1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs370103596, COSV100195374; called by muse, mutect2, varscan2
- FOXK1 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as rs778526385, COSV100194444; called by muse, mutect2, varscan2
- FOXN1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV56881727, COSV56884790; called by muse, mutect2, varscan2
- FOXRED2 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772698964, COSV53399956; called by muse, mutect2, varscan2
- FRAS1 | c.7316C>T p.T2439M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs541719823, COSV53606293; called by muse, mutect2, varscan2
- FREM1 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101083542; called by muse, mutect2, varscan2
- FRMD8 | c.1103G>A p.C368Y | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as rs1217148441, COSV58212583; called by muse, mutect2, varscan2
- FRMPD3 | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs759367486, COSV52188362; called by muse, varscan2
- FRMPD4 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV66224311; called by muse, mutect2, varscan2
- FRYL | c.8386G>A p.A2796T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as rs199599571; called by muse, mutect2, varscan2
- FSD2 | c.1646del p.G549Afs*4 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs1246402267; called by mutect2, pindel, varscan2
- FTSJ1 | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV99191371; called by muse, mutect2, varscan2
- FZD2 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59528612; called by muse, mutect2, varscan2
- G6PD | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as CM066825, COSV100854909; called by muse, mutect2, varscan2
- GABRG3 | c.51G>A p.A17= | Splice Region (SNP) | VAF 45/114 reads (39%) | catalogued as COSV100403618; called by muse, mutect2, varscan2
- GAK | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs138100414; called by muse, mutect2, varscan2
- GAL3ST1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs985871403, COSV58893711; called by muse, mutect2, varscan2
- GAL3ST2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs141048050; called by muse, mutect2, varscan2
- GALNT3 | c.1853G>A p.C618Y | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101204865; called by muse, mutect2, varscan2
- GALNTL6 | c.1015G>T p.G339* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | catalogued as COSV101559977; called by muse, mutect2
- GALR2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.93); catalogued as COSV100134703; called by muse, mutect2, varscan2
- GAS6 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs929257792, COSV59850293; called by muse, mutect2, varscan2
- GAS7 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101450047, COSV101450091; called by muse, mutect2, varscan2
- GATA1 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV100936634; called by muse, mutect2, varscan2
- GBP1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs372549555; called by muse, mutect2, varscan2
- GBP2 | c.1324A>G p.K442E | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.16); catalogued as COSV100975295; called by muse, mutect2, varscan2
- GCC2 | c.4997A>G p.N1666S | Missense Mutation (SNP) | VAF 170/464 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1253258219, COSV100474681; called by muse, mutect2, varscan2
- GCDH | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM1313437, COSV99535620; called by muse, mutect2, varscan2
- GCK | c.1174C>T p.R392C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1167124132, CM081272, CM980897, COSV99789866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCM1 | c.616T>C p.W206R | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.333); catalogued as COSV99451911; called by muse, mutect2, varscan2
- GCNA | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); catalogued as COSV101032327; called by muse, mutect2, varscan2
- GET4 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs754748449, COSV99768324; called by muse, mutect2, varscan2
- GFOD2 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs1395544712, COSV52057923, COSV52058456; called by muse, mutect2, varscan2
- GIN1 | c.212del p.K71Rfs*4 | Frame Shift Del (DEL) | VAF 144/404 reads (36%) | catalogued as rs1554196343; called by mutect2, pindel, varscan2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GJC3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV57210272; called by muse, mutect2, varscan2
- GK | c.1651G>A p.G551R (on ENST00000427190 / NM_001205019.2; = p.G545R on NM_001128127.2) | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.99); catalogued as COSV66735194; called by muse, mutect2, varscan2
- GKN1 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.2); catalogued as rs200701146, COSV65006798; called by muse, mutect2, varscan2
- GLI1 | c.2609del p.P870Lfs*76 | Frame Shift Del (DEL) | VAF 46/120 reads (38%) | catalogued as rs1565603031; called by mutect2, pindel, varscan2
- GLI3 | c.3595G>A p.V1199I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); catalogued as COSV67885817, COSV67890205; called by muse, mutect2, varscan2
- GLT8D2 | c.601-1G>T p.X201_splice | Splice Site (SNP) | VAF 32/86 reads (37%) | catalogued as COSV100673962; called by muse, mutect2, varscan2
- GLUD2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV60152132; called by muse, mutect2, varscan2
- GMDS | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101071370; called by muse, varscan2
- GMIP | c.2845A>G p.S949G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99179056; called by muse, mutect2, varscan2
- GMIP | c.2524G>T p.D842Y | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99179057; called by muse, mutect2, varscan2
- GMNN | c.274+2T>C p.X92_splice | Splice Site (SNP) | VAF 40/104 reads (38%) | catalogued as COSV57776900; called by muse, mutect2, varscan2
- GMPR2 | c.194A>G p.K65R (on ENST00000355299 / NM_001351022.2; = p.K83R on NM_016576.5) | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1226919098, COSV99164569; called by muse, mutect2, varscan2
- GNAS | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs773471190, COSV58331036; called by muse, mutect2, varscan2
- GNAT1 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99137156; called by muse, mutect2, varscan2
- GNB1L | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs746246670, COSV61548510; called by muse, mutect2, varscan2
- GNB3 | c.1000A>G p.S334G | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV99976661; called by muse, mutect2, varscan2
- GNPAT | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs375611364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100332063; called by muse, mutect2, varscan2
- GOLGA3 | c.4151A>G p.E1384G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV99201778; called by muse, mutect2, varscan2
- GOLM2 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100247590; called by muse, mutect2
- GPBAR1 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs927173480, COSV50307704; called by muse, mutect2, varscan2
- GPC1 | c.718-1G>T p.X240_splice | Splice Site (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99882440; called by muse, mutect2, varscan2
- GPC2 | c.1047del p.D350Tfs*24 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs748011069, COSV52786506; called by mutect2, varscan2
- GPHN | c.1733A>G p.E578G (on ENST00000315266 / NM_001377519.1; = p.E611G on NM_020806.5) | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59480508; called by muse, mutect2, varscan2
- GPR153 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as COSV100928424; called by muse, mutect2, varscan2
- GPR3 | c.38C>G p.S13* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100927470; called by muse, mutect2, varscan2
- GPR4 | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.99); catalogued as rs778870088, COSV59917015; called by muse, mutect2, varscan2
- GPS1 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152320; called by muse, mutect2, varscan2
- GPSM3 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs1406920851, COSV100900254; called by muse, mutect2, varscan2
- GRAMD1B | c.1510T>C p.Y504H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100454158; called by muse, mutect2, varscan2
- GRIA2 | c.1004C>A p.A335E | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.821); catalogued as COSV99642398; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as COSV58051797; called by mutect2, pindel, varscan2
- GRIN2A | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV100407439; called by muse, mutect2, varscan2
- GRIN2B | c.3899G>A p.R1300Q | Missense Mutation (SNP) | VAF 96/225 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757478003, COSV101662852; called by muse, mutect2, varscan2
- GRIN2D | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs774247271, COSV99615648; called by muse, mutect2, varscan2
- GRIN3B | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs1379928315, COSV99312006; called by muse, mutect2, varscan2
- GRINA | c.302A>G p.Q101R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.901); catalogued as COSV57592688; called by muse, mutect2, varscan2
- GRK3 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs764137519, COSV100150889; called by muse, mutect2, varscan2
- GRM1 | c.446del p.P149Qfs*11 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs1207726214, COSV51123015, COSV99267293; called by mutect2, pindel, varscan2
- GTF2E1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs140000454, COSV52204033; called by muse, mutect2, varscan2
- GTF2E1 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 43/99 reads (43%) | catalogued as COSV99381643; called by muse, mutect2, varscan2
- GTF2H4 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV99461326; called by muse, mutect2, varscan2
- GTF3C3 | c.2633C>T p.T878M | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs143599816; called by muse, mutect2, varscan2
- GZF1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs766072802, COSV57636094; called by muse, mutect2, varscan2
- H1-2 | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.985); catalogued as rs745376420, COSV100642206, COSV59192345; called by muse, mutect2, varscan2
- H2AC17 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs571168598, COSV58152639; called by muse, mutect2, varscan2
- H2BC6 | c.191A>G p.N64S | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as rs1381668292, COSV61591091; called by muse, mutect2, varscan2
- H3-3B | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV54666048; called by muse, mutect2, varscan2
- H4C12 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs779137595, COSV100694723; called by muse, mutect2, varscan2
- HAMP | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs765599115, COSV99723013; called by muse, mutect2, varscan2
- HAS1 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); catalogued as rs775182179, COSV55786197; called by muse, mutect2, varscan2
- HCFC1 | c.4138G>A p.A1380T | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs781897694, COSV100128232; called by muse, varscan2
- HDAC6 | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs782041149, COSV61931277; called by muse, mutect2, varscan2
- HDAC7 | c.71G>A p.R24H (on ENST00000427332; = p.R63H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371297447; called by muse, mutect2, varscan2
- HDAC9 | c.1616T>C p.L539P | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV67773263; called by muse, mutect2, varscan2
- HDLBP | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs141380467; called by muse, mutect2, varscan2
- HDLBP | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV100189642; called by muse, mutect2, varscan2
- HDX | c.756C>A p.D252E | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.978); catalogued as rs1271440832, COSV99946347; called by muse, mutect2, varscan2
- HEATR5B | c.6100C>T p.R2034C | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777159304, COSV51848465; called by muse, mutect2, varscan2
- HECTD1 | c.3220A>G p.N1074D | Missense Mutation (SNP) | VAF 128/301 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV101237283; called by muse, mutect2, varscan2
- HECTD4 | c.11851_11853del p.F3951del | In Frame Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs1189706170; called by pindel, varscan2
- HECTD4 | c.8455C>T p.R2819* | Nonsense Mutation (SNP) | VAF 64/173 reads (37%) | catalogued as COSV66386558; called by muse, mutect2, varscan2
- HECW1 | c.2984G>A p.R995H | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.022); catalogued as rs774693537, COSV67836059; called by muse, mutect2, varscan2
- HELZ2 | c.4717C>T p.R1573W (on ENST00000467148 / NM_001037335.2; = p.R1004W on NM_033405.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as rs147812640; called by muse, mutect2, varscan2
- HELZ2 | c.3056C>T p.T1019M (on ENST00000467148 / NM_001037335.2; = p.T450M on NM_033405.3) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs769150906, COSV100915382; called by muse, mutect2, varscan2
- HERC6 | c.1295C>A p.S432Y | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.325); catalogued as COSV52030070, COSV52032210; called by muse, mutect2, varscan2
- HEY2 | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100856250; called by muse, mutect2, varscan2
- HIF1A | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048345, COSV60188147; called by muse, mutect2, varscan2
- HJV | c.662C>G p.T221S (on ENST00000336751 / NM_213653.4; = p.T108S on NM_145277.5) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV100382161; called by muse, mutect2, varscan2
- HK3 | c.707C>A p.P236Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.139); catalogued as rs147991837, COSV99457538; called by muse, mutect2, varscan2
- HLA-DQB1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV66571634, COSV66573558; called by muse, mutect2, varscan2
- HLA-DRA | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.353); catalogued as COSV100895030; called by muse, mutect2, varscan2
- HMCN1 | c.7987G>T p.V2663L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99622272; called by muse, mutect2, varscan2
- HMGXB4 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99329834; called by muse, mutect2, varscan2
- HNRNPL | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.446); catalogued as rs1187823491, COSV99669850; called by muse, mutect2, varscan2
- HOMER3 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs751165867, COSV55356101; called by muse, mutect2, varscan2
- HOXA3 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1212072086, COSV57829097; called by muse, mutect2, varscan2
- HOXC4 | c.424del p.I142Ffs*6 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | catalogued as rs754429960; called by mutect2, pindel, varscan2
- HOXC9 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs762217624, COSV100327347; called by muse, mutect2, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs770632206; called by mutect2, pindel, varscan2
- HRG | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201213205, COSV99214447; called by muse, mutect2, varscan2
- HROB | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771236546, COSV55369011; called by muse, mutect2, varscan2
- HS6ST2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63713011; called by muse, mutect2, varscan2
- HSP90AA1 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99354953; called by muse, mutect2, varscan2
- HSPA14 | c.284del p.N95Mfs*8 | Frame Shift Del (DEL) | VAF 77/227 reads (34%) | catalogued as rs760011797; called by mutect2, pindel, varscan2
- HSPA2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99904652; called by muse, mutect2, varscan2
- HSPG2 | c.9980C>T p.P3327L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1486823445, COSV101013287; called by muse, mutect2, varscan2
- HTATSF1 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs1396759818, COSV54479493; called by muse, mutect2, varscan2
- HTR3A | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs763753633, COSV100248198; called by muse, mutect2, varscan2
- IBTK | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370183816, COSV60395545; called by muse, mutect2, varscan2
- ICAM1 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.225); catalogued as rs370415118; called by muse, mutect2, varscan2
- ICAM4 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV53425036; called by muse, mutect2, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFITM3 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV101296756; called by muse, mutect2
- IFNA8 | c.187del p.Q63Rfs*21 | Frame Shift Del (DEL) | VAF 37/95 reads (39%) | catalogued as rs762864128; called by mutect2, pindel, varscan2
- IFNL2 | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100122024; called by muse, mutect2, varscan2
- IFNL3 | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV69830027; called by muse, mutect2, varscan2
- IFT172 | c.2443-2A>G p.X815_splice | Splice Site (SNP) | VAF 38/96 reads (40%) | catalogued as COSV99561498; called by muse, mutect2, varscan2
- IFT52 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100887505; called by muse, mutect2, varscan2
- IFT74 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV66286995; called by muse, mutect2, varscan2
- IFT81 | c.1601G>T p.S534I | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV54362506; called by muse, mutect2, varscan2
- IGDCC3 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1201380354, COSV60079755; called by muse, mutect2, varscan2
- IGF1 | c.579del p.G194Efs*8 | Frame Shift Del (DEL) | VAF 32/290 reads (11%) | catalogued as rs1565968684, COSV61032034; called by mutect2, pindel, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 40/80 reads (50%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFBP4 | c.123del p.V42Wfs*52 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs778799414; called by mutect2, pindel, varscan2
- IGFN1 | c.3095G>A p.S1032N (on ENST00000295591 / NM_001367841.1; = p.S3489N on NM_001164586.2) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.475); catalogued as COSV99810750; called by muse, mutect2, varscan2
2,152 further variants in this file (1,461 protein-altering or splice-affecting, 640 silent, 51 other) are not listed here.
